Surgical pathology report (de-identified scan), TCGA case TCGA-29-1781, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1781-01A (Primary Tumor).

[page 1 of 4]
CLINICAL HISTORY:

History of breast cancer-new pelvic mass CA 125 =1625.

GROSS EXAMINATION:

A. "Omentum (AF1)". Received fresh for frozen section is a 14.5 x 9.9 x 3.8 cm aggregate of yellow lobulated adipose tissue. There are multiple tan-white firm nodules ranging from 0.4 cm to 2.9 cm in greatest dimension comprising approximately 55% of the specimen. Focal areas of central softening and hemorrhage are identified. A representative section is submitted as frozen section AF1. The frozen section remnant is submitted in block A1. An additional representative section is submitted in block A2.

B. "Omentum". Received fresh and placed in formalin on [REDACTED] is a 18 x 13.5 x 4 cm aggregate of yellow lobulated adipose tissue. There are multiple tan-white firm nodules ranging from 0.2 cm to 3.5 cm in greatest dimension comprising approximately 40% of the specimen with focal areas of softening, hemorrhage, and necrosis are identified. Representative sections are submitted in blocks B1-B2.

C. "Appendix". Received fresh and placed in formalin on [REDACTED] is a 7 cm long x 0.6 cm in diameter intact vermiform appendix. Upon sectioning, the lumen is patent with an average wall thickness of 0.3 cm. The distal tip is questionable for wall thickening. The mesenteric fat (1.5 cm) is remarkable for multiple tan-white firm nodules ranging from 0.2 cm up to 1.6 cm in greatest dimension.

BLOCK SUMMARY:

C1- proximal margin (inked blue), appendiceal cross sections and tip (longitudinal).

C2- nodules.

D. "Right tube and ovary". Received fresh and placed in formalin on [REDACTED] is a 42.1 gram, 2.8 x 2.1 x 1.5 cm right ovary and attached fimbria. No portion of tube is grossly identified. The ovary is focally disrupted with with adherent tan-white firm nodules ranging from 0.2 cm to 1.1 cm in greatest dimension. Sectioning reveals complete effacement of the ovarian parenchyma by tan-white nodules with marked areas of necrosis and hemorrhage, which are contiguous with the aforementioned surface nodules.

Attached to the ovary is a 9 x 3 x 1.6 cm fragment of soft tissue. There are multiple firm tan-white nodules ranging from 0.4 cm to 1.9 cm in greatest dimension. Sectioning of the nodules reveal a tan-white cut surface with central areas of softening and hemorrhage.

BLOCK SUMMARY:

D1- ovary with adjacent disruption (capsule and disruption- blue).

D2- ovary with overlying capsule (capsule-blue).

D3- ovary with overlying capsule, (capsule-blue).

D4- fimbria

D5- soft tissue nodules.

E. "Left tube and ovary". Received fresh and placed in formalin on [REDACTED] is a 31.3 gram, 4 x 3.4 x 2.7 cm left ovary with an attached portion of fallopian tube (1.9 cm long x 0.4 cm in diameter) and fimbria. The ovary is intact with multiple tan-white firm nodules adherent to the surface. Sectioning reveals complete effacement of the ovarian parenchyma by tan-white

[page 2 of 4]
nodules with areas of frank necrosis, hemorrhage and cystic spaces.

Also attached is a 3.9 x 2.5 x 1 cm fragment of soft tissue. There are multiple firm, tan-white nodules which upon sectioning reveals a homogenous white cut surface with areas of focal hemorrhage.

BLOCK SUMMARY:

E1-E3- ovary with overlying capsule (capsule-blue)
E4- fallopian tube and fimbria.
E5- soft tissue nodules.

F. "Uterus and cervix". Received fresh and placed in formalin on [REDACTED] is a 55.2 gram, 6.8 x 4 x 1.8 cm hysterectomy specimen. There are multiple firm, tan-white nodules on the anterior serosa ranging from 0.3 cm to 0.9 cm in greatest dimension. The remainder of the serosa is focally erythematous. The ectocervix (2.5 x 2.4 cm) is tan-white, smooth and glistening with a central patent os (1.2 cm). The specimen is opened to reveal a 2.1 x 3.6 cm endometrial cavity lined by a 0.2 cm endometrium which overlies a 1.8 cm thick myometrium. One of the nodules on the anterior surface invades into the myometrium 0.4 cm from the endometrium, and has a tan-white cut surface with central softening.

BLOCK SUMMARY:

F1- anterior endo and ectocervix.
F2- posterior endo and ectocervix.
F3- anterior endomyometrium with invading nodule.
F4- anterior endomyometrium.
F5-F6- posterior endomyometrium.
F7-F8- soft tissue nodules.

G. "Mesenteric nodule". Received fresh and placed in formalin on [REDACTED] is a 2.4 x 2.2 x 0.5 cm aggregate of tan-white firm tissue. The specimen is entirely submitted in blocks G1-G2.

H. "Sigmoid colon". Received fresh and placed in formalin on [REDACTED] is a 20.7 cm long x 3.8 cm in circumference segment of unoriented colon with attached mesenteric fat. The serosa is remarkable for diffuse firm, tan-white nodules ranging from 0.2 cm to 2.9 cm in greatest dimension. There is no gross invasion of the nodules through the muscularis. The colonic mucosa is tan-brown and grossly unremarkable.

BLOCK SUMMARY:

H1-3- margins, tangential.
H4-H5- serosal nodules adjacent to colonic mucosa.

I. "Sigmoid donut". Received fresh and placed in formalin on [REDACTED] is a 3 x 2.1 x 0.6 cm aggregate of two fragments of tissue consistent with colon. The specimen is unremarkable and submitted entirely in blocks I1-I3.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- carcinoma present

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the [REDACTED] if they may not be cleared or approved by [REDACTED] The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical

[page 3 of 4]
TCGA-29-1781

purposes. They should not be regarded as investigational or for research. This [REDACTED]
[REDACTED] as qualified to perform high complexity clinical testing.

PATHOLOGIC STAGE:

PROCEDURE: Oophorectomy omentectomy appendectomy and partial colectomy.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMx

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM (AF1)":

OMENTUM WITH EXTENSIVE METASTATIC POORLY DIFFERENTIATED CARCINOMA, SEE COMMENT.
MAXIMUM TUMOR SIZE OF INDIVIDUAL NODULE: 2.9 CM.

B. "OMENTUM" (PARTIAL RESECTION):

OMENTUM WITH POORLY DIFFERENTIATED CARCINOMA.
MAXIMUM SIZE OF INDIVIDUAL TUMOR NODULE: 3.5 CM.

C. "APPENDIX":

ADENOCARCINOID TUMOR OF TIP OF APPENDIX, SEE COMMENT.
MAXIMUM SIZE OF TUMOR: 1.2 CM.
EXTENT OF INVASION: TUMOR EXTENDS FROM MUCOSA THROUGH MUSCULARIS PROPRIA MINIMALLY INTO SUBSEROUS ADIPOSE TISSUE.
VASCULAR INVASION: NEGATIVE.
MARGINS: NEGATIVE FOR TUMOR.

SEROUS POORLY DIFFERENTIATED ADENOCARCINOMA, SEE COMMENT.
MAXIMUM SIZE OF SEROUS METASTASIS: 1.6 CM.

D. "RIGHT TUBE AND OVARY":

"RIGHT OVARY":

TYPE: POORLY DIFFERENTIATED ADENOCARCINOMA, SEE COMMENT.
FIGO GRADE: 3
TUMOR SIZE: 2.8 X 2.1 CM.
WEIGHT: 42 GRAMS
SEROUS: POSITIVE
ADDITIONAL FINDINGS: FALLOPIAN TUBE, NEGATIVE FOR CARCINOMA.

E. "LEFT TUBE AND OVARY":

"LEFT OVARY":

TYPE: POORLY DIFFERENTIATED ADENOCARCINOMA
FIGO GRADE: 2
TUMOR SIZE: 4 X 3.4 CM.
WEIGHT: 31 GRAMS
SEROUS: POSITIVE FOR TUMOR
ADDITIONAL FINDINGS: FALLOPIAN TUBE NEGATIVE FOR CARCINOMA

[page 4 of 4]
TCGA-29-1781

F. UTERUS, 55 GRAMS

ENDOMETRIUM: INACTIVE

MYOMETRIUM: POSITIVE FOR POORLY DIFFERENTIATED ADENOCARCINOMA (EXTENSION FROM SEROSA), SEE COMMENT.

CERVIX: NO SPECIFIC PATHOLOGIC DIAGNOSIS.

SEROSEA: EXTENSIVE POORLY DIFFERENTIATED ADENOCARCINOMA.

SPECIMEN MARGINS: NEGATIVE FOR TUMOR.

G. "MESENTERIC NODULE":

POORLY DIFFERENTIATED ADENOCARCINOMA.

MAXIMUM SIZE OF TUMOR NODULE: 2.4 CM.

H. "SIGMOID COLON":

PORTION OF COLON WITH SEROSA POSITIVE FOR POORLY DIFFERENTIATED ADENOCARCINOMA.

MAXIMUM SIZE OF SEROSAL TUMOR NODULES: 2.4 CM.

MUCOSAL MARGINS NEGATIVE FOR TUMOR.

POSITIVE FOR VASCULAR INVASION.

I. "SIGMOID DONUT":

PORTION OF COLON, NEGATIVE FOR CARCINOMA.

COMMENT: [REDACTED] has reviewed portions of this case.

This patient has had a prior breast ductal carcinoma [REDACTED] removed at [REDACTED]. That tumor was reported to be weakly positive for estrogen receptor, negative for progesterone receptor, and negative for HER2/neu overexpression (repeat receptor analysis here has been requested, and will be reported separately). As described above, there are multiple areas of metastatic poorly differentiated carcinoma. Immunoperoxidase stains of the tumor in block D1 are positive for cytokeratin 7, CA125, and WT1 and are negative for BRST-2, CK20, mamoglobin, TTF-1, CDX2, and calretinin. This pattern of staining, along with the light microscopic appearance of the tumor, are most consistent with a primary ovarian adenocarcinoma, very poorly differentiated, presumably serous type.

In the tip of the appendix, there is an adenocarcinoid tumor ("goblet cell carcinoid"). This tumor is morphologically quite distinct from the much more extensive metastatic poorly differentiated adenocarcinoma. Immunostains of the adenocarcinoid tumor in block C1 of the appendix are positive for chromogranin, synaptophysin and cytokeratin 20 and are negative for cytokeratin 7.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 67eb3d4c-3832-40fe-99cc-890a6fef1049 (TCGA-29-1781.959C11FE-F170-49BC-A1FE-73B799741B93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).